Somatic mutation profile of tumor specimen 0DOA3O from CCDI case PBCAXG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Paraganglioma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 12.3 years (4,488 days).
Specimen 0DOA3O: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be0fa4c0-8205-49b3-bb0a-b92d30dfa8c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOA25 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87f8b948-cc05-4ec6-90ac-1789a6a4d6e1

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Silent 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NALCN | c.3530A>T p.D1177V | Missense Mutation (SNP) | VAF 118/544 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CYP4Z1 | c.1212G>T p.V404= | Silent (SNP) | VAF 29/287 reads (10%) | called by muse, mutect2, varscan2
